Somatic mutation profile of tumor specimen TCGA-16-1048-01B (aliquot TCGA-16-1048-01B-01D-1353-08) from TCGA case TCGA-16-1048, project TCGA-GBM (Glioblastoma Multiforme).
Specimen TCGA-16-1048-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c88306a-8eab-47ad-9342-4f501627a414.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-16-1048-10A (Blood Derived Normal), aliquot TCGA-16-1048-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d336cd05-a1a9-4d61-af68-a8ac23bb63a9

The open-access MAF lists 70 somatic variants for this specimen: 52 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 16, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 1, In Frame Del 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITIH6 | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 55/96 reads (57%) | catalogued as rs761191483; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 96/174 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AK7 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs751991167, COSV50870769; called by muse, mutect2, varscan2
- CD1C | c.260del p.L87Yfs*9 | Frame Shift Del (DEL) | VAF 50/181 reads (28%) | catalogued as COSV63807299; called by mutect2, pindel, varscan2
- CHAMP1 | c.1183C>G p.P395A | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs782673915; called by muse, mutect2, varscan2
- CNTN2 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs764275222, COSV59352121; called by muse, mutect2, varscan2
- COL6A5 | c.6359G>A p.R2120H (on ENST00000312481; = p.R2116H on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs146634521; called by muse, mutect2, varscan2
- CYP2B6 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs758750908; called by muse, mutect2, varscan2
- FOXA3 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1005769337, COSV56216422; called by muse, mutect2
- GABRA4 | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.433); catalogued as rs774499404; called by muse, mutect2, varscan2
- GCG | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.308); catalogued as rs202213699; called by muse, mutect2, varscan2
- KCNK17 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 70/388 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs142227833, COSV64686024; called by muse, mutect2, varscan2
- LRP2BP | c.79T>G p.F27V | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs770634290; called by muse, mutect2, varscan2
- MARVELD2 | c.1562C>T p.T521I | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs750561732; called by muse, mutect2, varscan2
- MC4R | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs536312911, CM096062; called by muse, mutect2, varscan2
- MNS1 | c.846_848del p.E282del | In Frame Del (DEL) | VAF 32/260 reads (12%) | catalogued as rs772432216; called by pindel, varscan2
- PCDHGA8 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.072); catalogued as COSV54016635, COSV99548902; called by muse, mutect2, varscan2
- PNLIP | c.202-1G>A p.X68_splice | Splice Site (SNP) | VAF 74/187 reads (40%) | catalogued as rs775339813, COSV65040583; called by muse, varscan2
- PPM1D | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 63/253 reads (25%) | catalogued as rs1296018768; called by muse, mutect2, varscan2
- SAMD9 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 76/387 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780363399, COSV66073530, COSV66076252; called by muse, mutect2, varscan2
- SLC22A9 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs143461929, COSV54169664; called by muse, mutect2, varscan2
- SLC4A5 | c.1486G>A p.G496S | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201823142, COSV61031075; called by muse, mutect2, varscan2
- TAS2R41 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs779872662, COSV68764906; called by muse, mutect2, varscan2
- TINAG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs115438249, COSV52508165; called by mutect2, varscan2
- TINAG | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs779047105; called by muse, mutect2, varscan2
- TMEM87B | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.272); catalogued as rs762089820; called by muse, mutect2, varscan2
- AHNAK2 | c.14560C>G p.P4854A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- AMY2B | c.342_345del p.N115Ifs*7 | Frame Shift Del (DEL) | VAF 177/936 reads (19%) | called by pindel, varscan2
- ANGPT4 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- BACH1 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- BIRC6 | c.9243A>T p.L3081F | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DLGAP2 | c.3161G>A p.R1054Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- DSE | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSP | c.3946G>A p.A1316T | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EGFR | c.760T>A p.F254I | Missense Mutation (SNP) | VAF 2344/2477 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBN2 | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FUT6 | c.325C>G p.H109D | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GPR179 | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IL18RAP | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- MAP3K7 | c.1729G>T p.E577* (on ENST00000369329 / NM_145331.3; = p.E550* on NM_003188.4) | Nonsense Mutation (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
- MYO1B | c.22A>T p.T8S | Missense Mutation (SNP) | VAF 87/282 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO3B | c.1474T>C p.F492L | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NDN | c.13A>T p.S5C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- OR8I2 | c.527T>C p.F176S | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2
- PARVG | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PTK7 | c.1666C>T p.H556Y | Missense Mutation (SNP) | VAF 134/338 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RELN | c.7726C>A p.Q2576K | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SLC19A3 | c.1094A>G p.Y365C | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SLC4A7 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- STIM1 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- TSC22D1 | c.1823C>A p.S608Y | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ZNF532 | c.1858G>T p.E620* | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- ALOX12B | c.153C>A p.G51= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- AQP5 | c.144G>A p.A48= | Silent (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- CFAP74 | c.1011C>T p.H337= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- CHRFAM7A | c.690C>T p.H230= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs371263130; called by muse, mutect2, varscan2
- COL28A1 | c.2736A>G p.K912= | Silent (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- GDPD4 | c.142C>T p.L48= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV60022290; called by muse, varscan2
- IGHV7-81 | c.225G>A p.G75= | Silent (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- ITGA4 | c.1233G>A p.S411= | Silent (SNP) | VAF 52/199 reads (26%) | catalogued as rs368002151; called by muse, mutect2, varscan2
- KRTAP12-3 | c.123G>A p.T41= | Silent (SNP) | VAF 71/247 reads (29%) | catalogued as rs782250308, COSV59976125; called by muse, mutect2, varscan2
- MOGAT2 | c.678C>T p.F226= | Silent (SNP) | VAF 50/177 reads (28%) | catalogued as rs745853807; called by muse, mutect2, varscan2
- NOS1 | c.3273G>A p.P1091= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as rs1004551488, COSV57608306; called by muse, mutect2, varscan2
- OR6K2 | c.654C>T p.S218= | Silent (SNP) | VAF 55/166 reads (33%) | called by muse, mutect2, varscan2
- PHF8 | c.2745G>A p.K915= (on ENST00000357988 / NM_001184896.1; = p.K879= on NM_015107.3) | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, varscan2
- SHTN1 | c.133C>A p.R45= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV53382220; called by muse, mutect2, varscan2
- SNED1 | c.2745G>A p.E915= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs754771309; called by muse, mutect2, varscan2
- SRRM2 | c.1545G>A p.R515= | Silent (SNP) | VAF 49/186 reads (26%) | catalogued as rs764944184; called by muse, mutect2, varscan2
- CD300LD | c.-27A>C | 5'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- IL9R | c.29-1477G>C | Intron (SNP) | VAF 121/511 reads (24%) | called by muse, mutect2, varscan2
